Somatic mutation profile of tumor specimen MBCProject_5856_T0B_WES (aliquot MBCProject_5856_T0B_WES_1) from CMI case MBCProject_5856, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 60.0 years (21,902 days).
Specimen MBCProject_5856_T0B_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3bd1fe53-9fc1-4b73-9739-d0ec1fef6f75.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_5856_SALIVA (Saliva), aliquot MBCProject_5856_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b5994fe5-9754-42ff-895a-3521899fc780

The open-access MAF lists 42 somatic variants for this specimen: 29 protein-altering or splice-affecting, 8 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 8, Intron 2, Frame Shift Del 2, RNA 1, 5'UTR 1, Splice Region 1, Nonsense Mutation 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSM5 | c.1417G>A p.D473N | Missense Mutation (SNP) | VAF 35/141 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776309636, COSV59375732; called by muse, mutect2, varscan2
- ATP2B2 | c.3298G>A p.E1100K (on ENST00000352432; = p.E1066K on NM_001683.5) | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.265); catalogued as rs772535893; called by muse, mutect2, varscan2
- CCKAR | c.100C>T p.R34C | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.347); catalogued as rs536379349; called by mutect2, varscan2
- DPM3 | c.225G>C p.Q75H (on ENST00000341298; = p.Q105H on NM_018973.3) | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.942); catalogued as COSV57597502; called by muse, mutect2
- FERMT1 | c.724G>A p.D242N | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs1399325233; called by muse, mutect2
- IRX6 | c.94C>A p.R32S | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.111); catalogued as rs779323756; called by muse, mutect2, varscan2
- MX1 | c.1328G>C p.R443T | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV55818793; called by muse, mutect2
- NELL2 | c.2377G>A p.E793K | Missense Mutation (SNP) | VAF 30/143 reads (21%) | SIFT tolerated (0.95); PolyPhen possibly damaging (0.664); catalogued as COSV61582488; called by muse, mutect2, varscan2
- PCDH15 | c.4169C>T p.P1390L | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100230577; called by muse, mutect2, varscan2
- PHYHD1 | c.417G>C p.Q139H | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.554); catalogued as rs1206830767; called by muse, mutect2
- TBRG4 | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.218); catalogued as rs1214359295; called by muse, mutect2, varscan2
- TMC3 | c.412G>A p.V138I | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs201479309; called by mutect2, varscan2
- ZNF385A | c.245G>A p.R82H (on ENST00000338010 / NM_001130967.3; = p.R62H on NM_015481.3) | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757518593; called by muse, mutect2, varscan2
- BTBD6 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 10/188 reads (5%) | SIFT tolerated (0.9); PolyPhen possibly damaging (0.632); called by muse, mutect2
- C5orf49 | c.226G>C p.E76Q | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CDH1 | c.801del p.F267Lfs*15 | Frame Shift Del (DEL) | VAF 29/97 reads (30%) | called by mutect2, pindel, varscan2
- CPEB1 | c.1006G>C p.E336Q (on ENST00000617958; = p.E276Q on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2
- EHF | c.140del p.P47Lfs*42 | Frame Shift Del (DEL) | VAF 36/147 reads (24%) | called by mutect2, pindel, varscan2
- ESR1 | c.1612G>A p.D538N | Missense Mutation (SNP) | VAF 14/214 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2
- GOLGA6L22 | c.379G>C p.E127Q | Missense Mutation (SNP) | VAF 15/177 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- HBP1 | c.1351G>C p.E451Q | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, varscan2
- LRRC8E | c.1967A>T p.E656V | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- MTUS2 | c.841G>C p.E281Q | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.698); called by muse, varscan2
- ODF2 | c.643G>A p.E215K (on ENST00000434106 / NM_153433.2; = p.E191K on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/157 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PHYHD1 | c.457+3G>C | Splice Region (SNP) | VAF 11/172 reads (6%) | called by muse, mutect2
- PTPRJ | c.2686C>T p.Q896* | Nonsense Mutation (SNP) | VAF 13/164 reads (8%) | called by muse, mutect2
- SEC14L6 | c.1185G>C p.E395D | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- TAS1R3 | c.301G>C p.D101H | Missense Mutation (SNP) | VAF 7/120 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- WDR24 | c.12G>C p.K4N | Missense Mutation (SNP) | VAF 17/224 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.024); called by muse, mutect2
- INCENP | c.2127G>A p.E709= (on ENST00000394818 / NM_001040694.2; = p.E705= on NM_020238.3) | Silent (SNP) | VAF 28/194 reads (14%) | catalogued as rs564813243; called by muse, mutect2, varscan2
- MAP3K1 | c.1752C>T p.L584= | Silent (SNP) | VAF 23/177 reads (13%) | catalogued as COSV101266924; called by muse, mutect2, varscan2
- MYO1B | c.2349C>G p.V783= | Silent (SNP) | VAF 33/174 reads (19%) | catalogued as rs768492272; called by muse, varscan2
- SYNE1 | c.15933G>C p.V5311= (on ENST00000367255 / NM_182961.4; = p.V5240= on NM_033071.3) | Silent (SNP) | VAF 12/130 reads (9%) | called by muse, mutect2
- TRIL | c.2322C>T p.L774= | Silent (SNP) | VAF 15/177 reads (8%) | called by muse, mutect2
- TTN | c.51195C>A p.A17065= (on ENST00000591111; = p.A9641= on NM_003319.4) | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV100593375, COSV100632445; called by mutect2, varscan2
- VPS13D | c.10173C>T p.Y3391= | Silent (SNP) | VAF 18/109 reads (17%) | called by muse, varscan2
- WDR91 | c.2190C>T p.T730= | Silent (SNP) | VAF 17/66 reads (26%) | catalogued as rs145873188; called by muse, mutect2, varscan2
- ATG12 | c.163+51G>A | Intron (SNP) | VAF 12/280 reads (4%) | called by muse, mutect2
- EPDR1 | c.-81G>A | 5'UTR (SNP) | VAF 8/77 reads (10%) | catalogued as rs768449778; called by mutect2, varscan2
- HOXB3 | c.-159+712G>A | Intron (SNP) | VAF 12/109 reads (11%) | called by muse, mutect2, varscan2
- PDXDC1 | chr16:14974730 A>T | 5'Flank (SNP) | VAF 20/207 reads (10%) | called by muse, mutect2, varscan2
- TMEM183B | n.144G>A | RNA (SNP) | VAF 34/142 reads (24%) | catalogued as rs757751312; called by muse, mutect2, varscan2
